Surgical pathology report (de-identified scan), TCGA case TCGA-2L-AAQM, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Technical University of Munich, specimen TCGA-2L-AAQM-01A (Primary Tumor).

Age: male

Surgery date:

Short report on diagnostic findings
Pancreatic carcinoma

Expansive, well differentiated neuroendocrine carcinoma of the pancreas with extension beyond the pancreas and infiltration of the posterior wall of the stomach with ulceration of the mucosa. Vessel infiltration. Lymphangiosis carcinomatosa (6.). Lymph node metastases (3.,6.), lymph nodes without tumor (1.,2.,4.,7.). anastomotic rings without tumor (8.), cholesteatosis of the gall bladder (9.). Invasion of the portal vein margin (5.).

TNM classification (UICC, 7th Edition 2010): pT3, pN1 (16/57), L1, V1.

Grading: G1

Resection status: R1 (caudal, proximal, and dorsal at the main specimen, vessel invasion with tumor thrombus (6.), portal vein (5.))

ICD-O-3
Carcinoma, neuroendocrine NOS
8246/3
Site: Pancreas NOS
C25.0
p 6/5/14

Criteria	hw 2/1/14	Yes	No

Source: NCI Genomic Data Commons file 3549ca9e-47bf-438a-8ca7-f23b0dbd85d2 (TCGA-2L-AAQM.4797C80B-B1BD-447A-BD5F-9150BCD94317.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).